CCDI case PBCCMF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/0d958fc2-3cba-4c21-869b-ae768cecc40e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 3.3 years (1,222 days).

Biospecimens (3 samples)
- Sample 0DP8QI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPE8Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPE9Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
